Somatic mutation profile of tumor specimen a2f03d85-5f1a-4b3e-9dbf-74e67e (aliquot a2f03d85-5f1a-4b3e-9dbf-74e67e_D6_1) from CPTAC case 22CO004, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen a2f03d85-5f1a-4b3e-9dbf-74e67e: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 01cb01df-9956-4c39-a6da-0c8ca105c464.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 263fea68-40db-4402-9b99-c93b0c (Blood Derived Normal), aliquot 263fea68-40db-4402-9b99-c93b0c_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/48285f0b-8f07-47c7-9097-77a7d82c1b6a

The open-access MAF lists 98 somatic variants for this specimen: 60 protein-altering or splice-affecting, 19 silent, 19 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 51, Silent 19, Intron 10, Nonsense Mutation 5, 5'UTR 3, 3'UTR 3, Splice Site 1, Splice Region 1, RNA 1, 3'Flank 1, Frame Shift Del 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SLC26A4 | c.2162C>T p.T721M | Missense Mutation (SNP) | VAF 48/262 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121908363, CM991031, COSV55920673; ClinVar: pathogenic; called by muse, mutect2, varscan2
- BCO2 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 13/54 reads (24%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.733); catalogued as rs1309701978, COSV63064243; called by muse, mutect2, varscan2
- BCORL1 | c.2939C>T p.T980M | Missense Mutation (SNP) | VAF 121/178 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.888); catalogued as rs755857508; called by muse, mutect2, varscan2
- CACNA1E | c.6191G>A p.R2064H (on ENST00000367573 / NM_001205293.3; = p.R2021H on NM_000721.4) | Missense Mutation (SNP) | VAF 28/95 reads (29%) | SIFT tolerated (0.45); PolyPhen possibly damaging (0.747); catalogued as rs779562850, COSV62416498; called by muse, mutect2, varscan2
- CHRD | c.2156C>T p.A719V | Missense Mutation (SNP) | VAF 51/267 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0.218); catalogued as rs368217568, COSV52607019; called by muse, mutect2, varscan2
- COL6A2 | c.2137C>T p.R713C | Missense Mutation (SNP) | VAF 92/344 reads (27%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.657); catalogued as rs139627965, COSV56015899; called by muse, mutect2
- COL6A6 | c.2707C>T p.R903W | Missense Mutation (SNP) | VAF 50/227 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.001); catalogued as rs768161608, COSV62026315; called by muse, mutect2, varscan2
- COLEC12 | c.1210G>T p.D404Y | Missense Mutation (SNP) | VAF 46/131 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV68372390; called by muse, mutect2, varscan2
- DNAI1 | c.2048C>T p.A683V | Missense Mutation (SNP) | VAF 125/454 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.217); catalogued as rs535760702, COSV54281101; called by muse, mutect2, varscan2
- HNRNPAB | c.991C>T p.P331S (on ENST00000504898; = p.P284S on NM_004499.4) | Missense Mutation (SNP) | VAF 37/135 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57422708; called by muse, mutect2, varscan2
- KCNK3 | c.520G>A p.G174S | Missense Mutation (SNP) | VAF 95/342 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100257320; called by muse, mutect2, varscan2
- LAMA2 | c.837G>T p.K279N | Missense Mutation (SNP) | VAF 25/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101370739; called by muse, mutect2, varscan2
- LMNB1 | c.1021G>T p.D341Y | Missense Mutation (SNP) | VAF 25/96 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.612); catalogued as COSV54400413; called by muse, mutect2, varscan2
- NLRP4 | c.2704G>T p.E902* | Nonsense Mutation (SNP) | VAF 28/116 reads (24%) | catalogued as rs772259410; called by muse, mutect2, varscan2
- OR10H1 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 47/153 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.588); catalogued as rs1349572473; called by muse, mutect2, varscan2
- PNPLA7 | c.2659G>A p.V887I | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT tolerated (0.34); PolyPhen benign (0.031); catalogued as rs1368315726; called by muse, mutect2
- POLE | c.155G>A p.R52Q | Missense Mutation (SNP) | VAF 27/102 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.158); catalogued as rs372459649; ClinVar: likely benign / conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- PRRC2C | c.512G>T p.S171I (on ENST00000367742; = p.S169I on NM_015172.4) | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as COSV58914814; called by muse, mutect2, varscan2
- RFTN1 | c.1091G>A p.S364N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.23); PolyPhen benign (0.015); catalogued as COSV100488955; called by mutect2, varscan2
- RFX2 | c.677G>A p.R226Q | Missense Mutation (SNP) | VAF 18/73 reads (25%) | SIFT tolerated (0.24); PolyPhen benign (0.251); catalogued as rs747394691; called by muse, mutect2, varscan2
- RP1 | c.6421A>G p.I2141V | Missense Mutation (SNP) | VAF 18/153 reads (12%) | SIFT tolerated (0.83); PolyPhen benign (0); catalogued as rs907744519; called by muse, mutect2, varscan2
- SCP2D1 | c.443G>A p.R148K | Missense Mutation (SNP) | VAF 19/87 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV99602137; called by muse, mutect2, varscan2
- SLC38A8 | c.1114G>A p.V372I | Missense Mutation (SNP) | VAF 77/293 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs369678357; called by muse, mutect2, varscan2
- SPOCK2 | c.708C>T p.S236= | Splice Region (SNP) | VAF 58/182 reads (32%) | catalogued as rs375998618; called by muse, mutect2, varscan2
- TSHZ3 | c.2350G>A p.V784I | Missense Mutation (SNP) | VAF 22/191 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs753027332; called by muse, mutect2, varscan2
- ADGRL2 | c.2680G>A p.E894K (on ENST00000370717 / NM_001366005.1; = p.E881K on NM_012302.4) | Missense Mutation (SNP) | VAF 10/192 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- AKAP8L | c.143G>T p.G48V | Missense Mutation (SNP) | VAF 56/228 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ALAS1 | c.1600G>A p.V534I | Missense Mutation (SNP) | VAF 59/179 reads (33%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.874); called by muse, mutect2, varscan2
- ARPP21 | c.409T>G p.C137G | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- BTN3A3 | c.391G>A p.G131S | Missense Mutation (SNP) | VAF 95/362 reads (26%) | SIFT tolerated (0.08); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- CACNA1G | c.5860G>A p.A1954T | Missense Mutation (SNP) | VAF 72/223 reads (32%) | SIFT deleterious (0.01); PolyPhen benign (0.169); called by muse, mutect2, varscan2
- COL16A1 | c.2537C>G p.P846R | Missense Mutation (SNP) | VAF 31/232 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- DCLRE1A | c.1591G>A p.A531T | Missense Mutation (SNP) | VAF 29/128 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.079); called by muse, mutect2, varscan2
- EPOR | c.759_776del p.T254_L259del | In Frame Del (DEL) | VAF 27/180 reads (15%) | called by mutect2, varscan2
- FAT4 | c.11017C>T p.Q3673* | Nonsense Mutation (SNP) | VAF 45/310 reads (15%) | called by muse, mutect2, varscan2
- FGF13 | c.43C>T p.Q15* | Nonsense Mutation (SNP) | VAF 103/133 reads (77%) | called by muse, mutect2, varscan2
- FLT4 | c.2981G>A p.R994Q | Missense Mutation (SNP) | VAF 73/237 reads (31%) | SIFT tolerated (0.34); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FRAS1 | c.140A>G p.Q47R | Missense Mutation (SNP) | VAF 13/113 reads (12%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- GAS2L1 | c.1336C>A p.L446I | Missense Mutation (SNP) | VAF 82/314 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- HGSNAT | c.1525G>A p.A509T | Missense Mutation (SNP) | VAF 35/156 reads (22%) | SIFT tolerated (0.47); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- LTBR | c.1273A>G p.R425G | Missense Mutation (SNP) | VAF 21/85 reads (25%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0); called by muse, mutect2, varscan2
- MVP | c.1502C>T p.S501L | Missense Mutation (SNP) | VAF 95/353 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- NCAPG | c.2560T>A p.L854M | Missense Mutation (SNP) | VAF 14/71 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NOD1 | c.2503G>T p.A835S | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- NOMO1 | c.3464A>G p.D1155G | Missense Mutation (SNP) | VAF 32/382 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); called by muse, mutect2
- NYNRIN | c.1690C>T p.P564S | Missense Mutation (SNP) | VAF 89/212 reads (42%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- OR10A3 | c.928A>T p.I310F | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT tolerated (0.9); PolyPhen benign (0.027); called by mutect2, varscan2
- OR2T3 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 39/671 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.006); called by muse, mutect2
- OR5T3 | c.7A>T p.K3* | Nonsense Mutation (SNP) | VAF 12/70 reads (17%) | called by mutect2, varscan2
- OSBP | c.2046A>C p.K682N | Missense Mutation (SNP) | VAF 5/92 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.906); called by muse, mutect2
- OTP | c.884G>A p.S295N | Missense Mutation (SNP) | VAF 73/236 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.954); called by muse, mutect2, varscan2
- PHF12 | c.983del p.N328Ifs*2 | Frame Shift Del (DEL) | VAF 21/84 reads (25%) | called by mutect2, pindel, varscan2
- PLD5 | c.151G>A p.A51T | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2
- SCNN1G | c.1240C>T p.Q414* | Nonsense Mutation (SNP) | VAF 56/294 reads (19%) | called by muse, varscan2
- SHCBP1L | c.232G>A p.A78T | Missense Mutation (SNP) | VAF 85/244 reads (35%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- SPTY2D1 | c.1285G>T p.V429F | Missense Mutation (SNP) | VAF 137/439 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.177); called by muse, mutect2, varscan2
- SVIL | c.2576_2586+3del p.X859_splice (on ENST00000355867 / NM_021738.3; = p.X433_splice on NM_003174.3 and 1 other RefSeq transcript) | Splice Site (DEL) | VAF 45/164 reads (27%) | called by mutect2, pindel, varscan2
- THSD7A | c.4145T>A p.V1382E | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT tolerated (0.94); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRPC4 | c.1775T>C p.F592S | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- XDH | c.2855A>T p.D952V | Missense Mutation (SNP) | VAF 130/489 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ADAM11 | c.1968G>T p.G656= | Silent (SNP) | VAF 91/376 reads (24%) | called by muse, mutect2, varscan2
- ADGRL3 | c.2289C>T p.D763= (on ENST00000506720 / NM_001322402.2; = p.D695= on NM_015236.6) | Silent (SNP) | VAF 24/159 reads (15%) | called by muse, mutect2, varscan2
- AP3D1 | c.2937G>A p.P979= | Silent (SNP) | VAF 56/168 reads (33%) | catalogued as rs544252608; called by muse, mutect2, varscan2
- CHRFAM7A | c.549C>T p.T183= | Silent (SNP) | VAF 48/212 reads (23%) | catalogued as rs558476222, COSV100241732; called by muse, mutect2, varscan2
- FBN1 | c.7827C>T p.N2609= | Silent (SNP) | VAF 36/366 reads (10%) | catalogued as rs764741627, COSV57330797; called by muse, mutect2, varscan2
- LDOC1 | c.408C>T p.D136= | Silent (SNP) | VAF 129/172 reads (75%) | catalogued as COSV100983116; called by muse, mutect2, varscan2
- LMF1 | c.684G>A p.G228= | Silent (SNP) | VAF 52/228 reads (23%) | catalogued as rs1438923480; called by muse, mutect2, varscan2
- METTL2A | c.348C>T p.F116= | Silent (SNP) | VAF 29/113 reads (26%) | called by muse, mutect2, varscan2
- OR8K3 | c.123C>A p.G41= | Silent (SNP) | VAF 79/300 reads (26%) | catalogued as rs774059151, COSV57131149, COSV57133176; called by muse, mutect2, varscan2
- PPP1R16B | c.1581G>A p.P527= | Silent (SNP) | VAF 20/196 reads (10%) | catalogued as rs757677700, COSV55376151; called by muse, mutect2
- RTN4IP1 | c.885C>T p.A295= | Silent (SNP) | VAF 11/95 reads (12%) | called by muse, mutect2, varscan2
- SLC1A6 | c.1149C>T p.T383= | Silent (SNP) | VAF 46/158 reads (29%) | catalogued as rs568967705, COSV99693792; called by muse, mutect2, varscan2
- TFPI2 | c.162C>T p.Y54= | Silent (SNP) | VAF 42/145 reads (29%) | catalogued as rs1486767937; called by muse, mutect2, varscan2
- TMEM131L | c.1998G>A p.T666= | Silent (SNP) | VAF 10/77 reads (13%) | catalogued as rs139178967, COSV99546618; called by muse, mutect2, varscan2
- TUBAL3 | c.102C>T p.G34= | Silent (SNP) | VAF 83/322 reads (26%) | catalogued as rs376910379; called by muse, mutect2, varscan2
- UCP2 | c.252C>T p.A84= | Silent (SNP) | VAF 100/406 reads (25%) | catalogued as rs749932912, COSV60104270; called by muse, mutect2, varscan2
- WNK1 | c.2559G>A p.T853= | Silent (SNP) | VAF 46/208 reads (22%) | catalogued as rs148818308; called by muse, mutect2, varscan2
- XKR4 | c.465C>A p.G155= | Silent (SNP) | VAF 27/301 reads (9%) | called by muse, mutect2
- ZNF334 | c.1068T>C p.N356= | Silent (SNP) | VAF 38/323 reads (12%) | called by muse, mutect2, varscan2
- AC009093.3 | chr16:29102107 del CTT | 3'Flank (DEL) | VAF 10/82 reads (12%) | called by pindel, varscan2
- AL353804.4 | chrX:73822782 C>T | 5'Flank (SNP) | VAF 29/67 reads (43%) | catalogued as rs1411004100; called by muse, mutect2, varscan2
- AP002008.2 | n.1443G>A | RNA (SNP) | VAF 36/138 reads (26%) | catalogued as rs954835574; called by muse, mutect2, varscan2
- ART3 | c.1003+912G>A | Intron (SNP) | VAF 12/116 reads (10%) | called by muse, mutect2
- CABP4 | c.367-72G>T | Intron (SNP) | VAF 76/286 reads (27%) | catalogued as rs757094726; called by mutect2, varscan2
- COL5A1 | c.109+7194C>G | Intron (SNP) | VAF 31/102 reads (30%) | called by muse, mutect2, varscan2
- COX11 | c.*5A>T | 3'UTR (SNP) | VAF 9/57 reads (16%) | called by muse, mutect2, varscan2
- CRTAC1 | c.1819+466G>T | Intron (SNP) | VAF 7/30 reads (23%) | called by muse, mutect2, varscan2
- FAS | c.*109G>C | 3'UTR (SNP) | VAF 46/179 reads (26%) | called by muse, mutect2, varscan2
- FXYD2 | c.65-17G>A | Intron (SNP) | VAF 141/486 reads (29%) | called by muse, mutect2, varscan2
- GABRG2 | c.-1G>A | 5'UTR (SNP) | VAF 36/108 reads (33%) | catalogued as rs780572044, COSV100729682; called by muse, mutect2, varscan2
- LATS1 | c.-186C>A | 5'UTR (SNP) | VAF 12/45 reads (27%) | called by muse, mutect2, varscan2
- LSP1 | c.54-9607C>T | Intron (SNP) | VAF 15/65 reads (23%) | catalogued as rs751559478; called by muse, mutect2, varscan2
- PLXDC1 | c.*4329G>A | 3'UTR (SNP) | VAF 26/94 reads (28%) | catalogued as rs373945265; called by muse, mutect2, varscan2
- PRAMEF11 | c.-11C>G | 5'UTR (SNP) | VAF 65/269 reads (24%) | catalogued as COSV101463187; called by muse, mutect2, varscan2
- PSMA3 | c.590+11A>T | Intron (SNP) | VAF 7/23 reads (30%) | catalogued as rs777352057; called by muse, mutect2, varscan2
- RUNX1T1 | c.1280-3856T>C | Intron (SNP) | VAF 14/131 reads (11%) | called by muse, mutect2
- SLC12A8 | c.737-82G>A | Intron (SNP) | VAF 45/193 reads (23%) | catalogued as rs534574930; called by muse, mutect2, varscan2
- SORBS1 | c.442-833G>A | Intron (SNP) | VAF 99/395 reads (25%) | catalogued as rs950831889; called by muse, mutect2, varscan2
